Gene-level copy-number profile of specimen HCM-CSHL-0147-C24-85A from HCMI case HCM-CSHL-0147-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,924 days).
Specimen HCM-CSHL-0147-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a08c7af-f36d-4a78-8ca2-3b6f0d818aff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0147-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,747 have no estimate.
https://portal.gdc.cancer.gov/files/88b87535-07dc-47e1-a3c1-530a566fc1c9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 29; copy number 2: 5,117; copy number 3: 798; copy number 4: 25,431; copy number 5: 508; copy number 6: 22,310; copy number 7: 1,132; copy number 8: 1,998; copy number 9: 1,496; copy number 10: 44; copy number 11: 2; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr13:87,379,472–87,380,258, 1 gene: LIN28AP2.
- chr13:87,427,200–87,447,235, 1 gene (within-gene range 0–2): AL360267.1.
- chr17:18,450,244–18,475,920, 4 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr22:21,341,595–21,358,067, 2 genes: PPP1R26P5, LINC01651.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,530 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 12: CFHR3.
- chr1:234,261,706–234,274,465, 2 genes, copy number 11 (within-gene range 8–11): AL122008.1, SLC35F3-AS1.
- chr2:89,252,211–89,862,981, 13 genes, copy number 10: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39.
- chr6:82,169,986–82,247,754, 2 genes, copy number 9: IBTK, RNU6-130P.
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 9 (broad region; genes not listed).
- chr14:19,688,261–19,700,650, 2 genes, copy number 10: ARHGAP42P4, AL512310.1.
- chr18:26,098,839–26,657,401, 14 genes, copy number 10 (within-gene range 6–10): RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057.
- chr19:27,638,483–27,646,483, 2 genes, copy number 10: ERVK-28, AC112702.1.

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
